Gene-level copy-number profile of tumor specimen TCGA-D1-A16G-01A from TCGA case TCGA-D1-A16G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,065 days).
Specimen TCGA-D1-A16G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3840de23-bdc6-44c8-8a40-70809b957822.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A16G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91656516-f1ae-46d6-959b-efaee78c604b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,956; copy number 2: 50,115; copy number 3: 5,293; copy number 4: 15; copy number 5: 100; copy number 6: 331; copy number 7: 7; copy number 18: 1; copy number 24: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A16G-01A-31D-A12G-01): tumor purity 0.36, ploidy 4.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 440 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:66,696,190–66,703,252, 1 gene, copy number 24: LINC01797.
- chr8:127,686,343–127,738,987, 1 gene, copy number 18 (within-gene range 2–18): CASC11.
- chr16:11,555–424,543, 37 genes, copy number 6: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1, MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1.
- chr16:439,297–439,397, 1 gene, copy number 6: Y_RNA.
- chr17:39,603,536–39,696,797, 7 genes, copy number 7: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3.
- chr19:27,638,483–38,773,492, 381 genes, copy number 5–6 (broad region; genes not listed).
- chr22:46,684,410–46,762,563, 2 genes, copy number 6 (within-gene range 3–6): CERK, AL118516.1.
- chr22:50,089,879–50,245,023, 10 genes, copy number 5 (within-gene range 3–5): MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6.

Autosomal genes at a single copy (total copy number 1): 3,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
